Somatic mutation profile of tumor specimen TCGA-55-8091-01A (aliquot TCGA-55-8091-01A-11D-2238-08) from TCGA case TCGA-55-8091, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75.0 years (27,385 days).
Specimen TCGA-55-8091-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a615e6c2-07d0-4bec-836f-c3dce658195a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8091-10A (Blood Derived Normal), aliquot TCGA-55-8091-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e4813e1-b5eb-4b90-8393-e60f44a50783

The open-access MAF lists 21 somatic variants for this specimen: 20 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 19, Silent 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs782356392, COSV53990957; called by muse, mutect2, varscan2
- ASTN1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs760958680, COSV56070701; called by muse, mutect2, varscan2
- DLGAP3 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs544160613, COSV99333167; called by muse, mutect2
- E2F7 | c.1449C>A p.F483L | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV59742279; called by muse, mutect2, varscan2
- EMB | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.801); catalogued as COSV100297019; called by muse, mutect2, varscan2
- KCNH8 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs1431768344, COSV60460323; called by muse, mutect2, varscan2
- MARS2 | c.926G>A p.G309D | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99986696; called by muse, mutect2, varscan2
- MYO1G | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 86/168 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs769604336, COSV51855791; called by muse, mutect2, varscan2
- OR2T11 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs758303018, COSV58187321; called by muse, mutect2, varscan2
- OR4N2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 54/826 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs746490349, COSV60050917; called by muse, mutect2
- PCDHA10 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); catalogued as rs782398517, COSV100254313; called by muse, mutect2, varscan2
- PIK3C2B | c.1384A>T p.M462L | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100915085; called by muse, mutect2
- PNMA8B | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100885530; called by muse, mutect2, varscan2
- PPWD1 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV99140252; called by muse, mutect2, varscan2
- REV3L | c.4912A>G p.S1638G | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100725679; called by muse, mutect2, varscan2
- SEZ6L | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs370293421; called by muse, mutect2, varscan2
- SKOR1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100408609; called by muse, mutect2, varscan2
- SMAD4 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100748241; called by muse, mutect2, varscan2
- TRPM1 | c.4559G>A p.R1520H | Missense Mutation (SNP) | VAF 148/356 reads (42%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs554416392, COSV56640470; called by muse, mutect2, varscan2
- TTN | c.6953G>A p.R2318H (on ENST00000591111; = p.R2272H on NM_003319.4) | Missense Mutation (SNP) | VAF 46/139 reads (33%) | PolyPhen probably damaging (0.998); catalogued as rs761566436, COSV60182770; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC40 | c.78C>T p.S26= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99661489; called by muse, mutect2, varscan2
